Somatic mutation profile of tumor specimen TCGA-BG-A0RY-01A (aliquot TCGA-BG-A0RY-01A-11D-A10B-09) from TCGA case TCGA-BG-A0RY, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 68.3 years (24,952 days).
Specimen TCGA-BG-A0RY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4c33489-6f88-4ae0-b009-4ed1670a8b3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BG-A0RY-10A (Blood Derived Normal), aliquot TCGA-BG-A0RY-10A-02D-A10B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f57d86a1-74ad-419e-b025-ebff9bf2f337

The open-access MAF lists 57 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 12, Nonsense Mutation 3, Frame Shift Ins 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 15/45 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- METTL14 | c.893G>C p.R298P | Missense Mutation (SNP) | VAF 56/115 reads (49%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66310162, COSV66310354; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 55/88 reads (63%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 80/91 reads (88%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- SOS1 | c.1655G>A p.R552K | Missense Mutation (SNP) | VAF 85/150 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs397517154, CM070273, CM095735, CM116030, COSV67674782, COSV67675536; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 91/212 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1387356833, COSV55945226, COSV55959906; called by muse, mutect2, varscan2
- ABRAXAS2 | c.947A>G p.Q316R | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.037); catalogued as COSV53717372; called by muse, mutect2, varscan2
- ADAM22 | c.1583A>G p.H528R | Missense Mutation (SNP) | VAF 113/248 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV55979992; called by muse, mutect2, varscan2
- ANKRD11 | c.3317A>G p.K1106R | Missense Mutation (SNP) | VAF 58/141 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV56363199; called by muse, mutect2, varscan2
- ARHGEF28 | c.2885T>G p.V962G | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55259542; called by muse, mutect2
- ASTN1 | c.3623G>A p.R1208Q | Missense Mutation (SNP) | VAF 140/198 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs768973979, COSV62496507; called by muse, mutect2, varscan2
- ATRX | c.3227C>G p.S1076C | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV100971538, COSV64878219; called by muse, mutect2, varscan2
- CDON | c.1859A>G p.D620G | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54999062; called by muse, mutect2, varscan2
- EGR2 | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | catalogued as COSV54347309; called by muse, mutect2, varscan2
- EP300 | c.181del p.I61Lfs*55 | Frame Shift Del (DEL) | VAF 36/91 reads (40%) | catalogued as COSV54335035; called by mutect2, pindel, varscan2
- EPHA8 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1391875727, COSV51272925, COSV99384177; called by muse, mutect2, varscan2
- FAM168B | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV66303750; called by muse, mutect2, varscan2
- FBLN1 | c.152C>G p.S51W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV53044161, COSV53049144; called by muse, mutect2, varscan2
- GPR68 | c.521A>T p.E174V | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53176624; called by muse, mutect2, varscan2
- KCNK3 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57192963; called by muse, mutect2, varscan2
- LRRK2 | c.5041G>A p.E1681K | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV54156915; called by muse, mutect2
- MEDAG | c.628C>T p.L210F | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as COSV66850416; called by muse, mutect2, varscan2
- MST1R | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs759008251, COSV56569977; called by muse, mutect2
- PALM2AKAP2 | c.277A>C p.I93L (on ENST00000374531 / NM_001037293.2; = p.I91L on NM_007203.5) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.992); catalogued as COSV57123129; called by muse, mutect2, varscan2
- PCDHB16 | c.2280A>T p.E760D | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.04); catalogued as COSV53364209; called by muse, mutect2, varscan2
- PIAS4 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV53679609; called by muse, mutect2, varscan2
- PRKG2 | c.902G>A p.C301Y | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as COSV52325849; called by muse, mutect2, varscan2
- PROKR1 | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV58137924; called by muse, mutect2
- RABGAP1L | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760616082, COSV52302621; called by muse, mutect2
- RAG2 | c.1163C>A p.A388E | Missense Mutation (SNP) | VAF 84/216 reads (39%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.626); catalogued as rs958911693, COSV57558084, COSV57558103, COSV57558169; called by muse, mutect2, varscan2
- RDH11 | c.160G>C p.G54R | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67282588, COSV67282854; called by muse, mutect2, varscan2
- SASH1 | c.569T>G p.I190S | Missense Mutation (SNP) | VAF 74/148 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66562651; called by muse, mutect2, varscan2
- SCD | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.05); catalogued as rs535091618, COSV64853302; called by muse, mutect2, varscan2
- SEMA3D | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 28/96 reads (29%) | catalogued as rs779806663, COSV52396179, COSV52397497; called by muse, mutect2, varscan2
- SLC47A2 | c.1625C>T p.T542M | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs368144909; called by muse, mutect2, varscan2
- SPPL2B | c.1237C>T p.P413S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV66317084; called by muse, mutect2, varscan2
- SPRR2G | c.118C>A p.P40T | Missense Mutation (SNP) | VAF 104/162 reads (64%) | PolyPhen benign (0.003); catalogued as COSV64203159; called by muse, mutect2, varscan2
- SSR4 | c.196C>G p.L66V | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51247549; called by muse, mutect2, varscan2
- TBRG4 | c.1609G>A p.V537I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs762142094, COSV51833161; called by muse, mutect2, varscan2
- THOC2 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV55548652; called by muse, mutect2, varscan2
- TMEM242 | c.178T>C p.W60R | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV65654216; called by muse, mutect2, varscan2
- WDR6 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs375289819, COSV58245419; called by muse, mutect2, varscan2
- PRPS2 | c.496_502dup p.V168Dfs*6 | Frame Shift Ins (INS) | VAF 26/86 reads (30%) | called by mutect2, varscan2
- RUNX2 | c.1443dup p.L482Afs*8 (on ENST00000371438; = p.L460Afs*8 on NM_001015051.3) | Frame Shift Ins (INS) | VAF 18/55 reads (33%) | called by mutect2, pindel, varscan2
- ARHGDIB | c.453G>A p.E151= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as COSV56763707; called by muse, mutect2
- AXL | c.627C>T p.N209= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs757927991, COSV56568837; called by muse, mutect2, varscan2
- DCDC2B | c.942G>A p.E314= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs761935416, COSV59084640; called by muse, mutect2, varscan2
- FAM217B | c.162G>A p.P54= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as rs150410816; called by muse, mutect2, varscan2
- HOXD10 | c.462G>A p.L154= | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as COSV50900620; called by muse, mutect2, varscan2
- MNDA | c.675C>T p.Y225= | Silent (SNP) | VAF 22/137 reads (16%) | catalogued as COSV63740681, COSV63740858; called by muse, mutect2, varscan2
- PCDH11X | c.1326C>T p.G442= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV53475506; called by muse, mutect2, varscan2
- POLR1B | c.1044C>T p.L348= | Silent (SNP) | VAF 32/127 reads (25%) | catalogued as rs760932513, COSV54499556; called by muse, mutect2, varscan2
- RNF213 | c.9129C>T p.L3043= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs142491605; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC6A17 | c.1887G>A p.T629= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs139019064, COSV58995443; called by muse, mutect2, varscan2
- ZNF572 | c.1461G>T p.R487= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV60002083; called by muse, mutect2, varscan2
- ZNF609 | c.438G>A p.A146= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as rs778288032, COSV58585092; called by muse, mutect2, varscan2
- GGNBP1 | n.846+1001G>A | Intron (SNP) | VAF 11/20 reads (55%) | catalogued as rs1008564494; called by muse, mutect2, varscan2
